Somatic mutation profile of tumor specimen BA2082D (aliquot aq-BA2082D) from BEATAML1.0 case 2126, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,587 days).
Specimen BA2082D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bc629fe-b548-4646-b218-a0688f642e80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2076D (Solid Tissue Normal), aliquot aq-BA2076D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4957051b-5914-4478-92b2-579e01028c5e

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDON | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751341846; called by muse, mutect2, varscan2
- TET2 | c.5270del p.H1757Lfs*6 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as rs1267214769; called by mutect2, pindel, varscan2
- VARS2 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1256915652, COSV99461581; called by muse, mutect2, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs749403447; called by mutect2, varscan2
- AL645922.1 | c.3155T>C p.I1052T | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2
- FBLL1 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTF1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MYH4 | c.4870G>A p.G1624R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NEURL4 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.396); called by muse, mutect2
- OR9K2 | c.951C>A p.N317K (on ENST00000305377; = p.N295K on NM_001005243.1) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- POU2F1 | c.485C>A p.T162K (on ENST00000541643 / NM_001365848.1; = p.T185K on NM_002697.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- RSBN1L | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZKSCAN1 | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- AC024598.1 | c.1119G>A p.T373= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs370509330; called by muse, mutect2, varscan2
- CTNND2 | c.18G>A p.P6= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs1222234904; called by muse, mutect2, varscan2
- FGFR2 | c.1044T>A p.I348= | Silent (SNP) | VAF 97/193 reads (50%) | called by muse, mutect2, varscan2
- HEY1 | c.474C>T p.L158= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as COSV100559152, COSV61232817; called by muse, mutect2, varscan2
- PTPRU | c.2679C>A p.G893= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100112463; called by muse, mutect2
- CADM1 | c.1079-26C>G | Intron (SNP) | VAF 49/125 reads (39%) | catalogued as rs1196084534; called by muse, mutect2, varscan2
